CCDI case PBCKDN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/af410a7e-2cba-42a8-bc93-558be92b9911

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Abdominal esophagus; Age at diagnosis: 2.4 years (863 days).

Biospecimens (3 samples)
- Sample 0DVCDO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVCF2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVCFM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
